Surgical pathology report (de-identified scan), TCGA case TCGA-BQ-5881, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BQ-5881-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

130
5881

Diagnosis & History:

with renal tumor.

Specimens Submitted:

1: SP: Right lower pole kidney, tumor, partial nephrectomy

2: SP: Deep margin

DIAGNOSIS:

1. SP: Right lower pole kidney, tumor, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Papillary type

Type 2 (High grade)

Tumor Size:

Greatest diameter is 3.1 cm.

Local Invasion (for renal cortical types):

Not Identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

2. SP: Deep margin, excision(fs) (pjm):

-Benign renal parenchyma.

[page 2 of 2]
I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL) AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh and labeled "right lower pole kidney tumor" and consists of two irregular fragments of tumor with kidney margin measuring 3.5 x 2 x 1 cm. The tumor measures 3.1 x 3 cm. The kidney margin is inked blue. TPS is taken. A representative section is submitted for frozen. Representative sections are submitted in two cassettes.

Summary of sections:
T-Tumor with inked margin.
FSC-frozen section control

2). The specimen is received fresh labeled "deep margin" and consists of two pieces of red soft tissue measuring in aggregate 1.5 x 1 x 0.2 cm. Entirely submitted for frozen section.

Summary of sections:
FSC-frozen section control

Summary of Sections:

Part 1: SP: Right lower pole kidney, tumor, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
2	t	2

Part 2: SP: Deep margin

Block	Sect. Site	PCs
1	fsc	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS RENAL CORTICAL NEOPLASM.
PERMANENT DIAGNOSIS: SAME
- 2) FROZEN SECTION DIAGNOSIS DEEP MARGIN FREE OF TUMOR
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file d98bcf35-9e82-4a9a-b6bc-94459841e739 (TCGA-BQ-5881.91C83E3D-783B-45B6-80B3-0281D6901E86.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).